Somatic mutation profile of tumor specimen TCGA-RD-A8N5-01A (aliquot TCGA-RD-A8N5-01A-12D-A364-08) from TCGA case TCGA-RD-A8N5, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 78.3 years (28,589 days).
Specimen TCGA-RD-A8N5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe2a2633-182c-4a6a-9dcc-4e0ef4fec3cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RD-A8N5-10A (Blood Derived Normal), aliquot TCGA-RD-A8N5-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17d008ac-c2e5-4cb7-b14d-2a473027b1ab

The open-access MAF lists 29 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 22, Silent 4, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACIN1 | c.2959T>G p.S987A | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.912); catalogued as COSV99399350; called by muse, mutect2
- AKAP9 | c.8906G>A p.G2969E (on ENST00000359028; = p.G2945E on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62355772; called by muse, mutect2
- CABIN1 | c.5899C>T p.R1967C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as COSV54085149; called by muse, mutect2, varscan2
- CACNA1A | c.1386G>T p.K462N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100801797; called by muse, mutect2, varscan2
- CAPZA1 | c.101A>G p.N34S | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs202216073, COSV99583018; called by muse, mutect2, varscan2
- COL17A1 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs533717233, COSV62227880; called by muse, mutect2, varscan2
- ERCC6 | c.3296G>A p.S1099N | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100875824; called by muse, mutect2
- HECTD2 | c.1477A>T p.S493C | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); catalogued as COSV99978368; called by muse, mutect2
- HMCN1 | c.12832C>T p.R4278* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as rs769844693, COSV54893489; called by muse, mutect2
- MBD5 | c.2098T>C p.S700P | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV101290010; called by muse, mutect2, varscan2
- NELL2 | c.336G>A p.R112= | Splice Region (SNP) | VAF 8/76 reads (11%) | catalogued as COSV100419188; called by muse, mutect2
- P2RY8 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1234101368; called by muse, mutect2
- PCDHA1 | c.2263C>T p.R755W | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs782576028, COSV65372482; called by muse, mutect2, varscan2
- PCDHA13 | c.465T>A p.D155E | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV99165490; called by muse, mutect2, varscan2
- PCDHGA4 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.011); catalogued as rs753002448, COSV53945296; called by mutect2, varscan2
- PLK1 | c.1621C>T p.L541F | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV99891037; called by muse, mutect2
- POGLUT2 | c.775T>A p.S259T | Missense Mutation (SNP) | VAF 13/317 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101050779; called by muse, mutect2
- PPAN-P2RY11 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 10/128 reads (8%) | catalogued as rs1439626532, COSV99461097; called by muse, mutect2
- SCAF8 | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63200154; called by muse, mutect2, varscan2
- SLC32A1 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV99462008; called by muse, mutect2
- SLC36A4 | c.1093A>G p.I365V | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs767252295, COSV100419301; called by muse, mutect2, varscan2
- SMYD3 | c.304G>T p.V102F (on ENST00000490107 / NM_001375962.1; = p.V43F on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771269963, COSV101193786, COSV66453454; called by muse, mutect2, varscan2
- TAF1L | c.5090C>T p.T1697I | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99644387; called by muse, mutect2, varscan2
- UBQLNL | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs376018623; called by mutect2, varscan2
- ZNF224 | c.1232C>G p.T411R | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.05); catalogued as COSV61243888; called by mutect2, varscan2
- KATNAL1 | c.819G>A p.S273= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs758914504, COSV101016792; called by muse, mutect2, varscan2
- MAB21L2 | c.882G>A p.S294= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs1003204803, COSV58261853; called by muse, mutect2, varscan2
- SLITRK5 | c.1995G>T p.V665= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100280554; called by muse, mutect2, varscan2
- ZNF43 | c.1623A>G p.E541= | Silent (SNP) | VAF 6/83 reads (7%) | catalogued as COSV100731754; called by muse, mutect2
